Gene-level copy-number profile of tumor specimen TCGA-D3-A5GS-06A from TCGA case TCGA-D3-A5GS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.6 years (21,393 days).
Specimen TCGA-D3-A5GS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.1ffb4b35-56ff-4390-a8b1-25aadfeca5dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A5GS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/851b57d1-b828-40b2-9d88-33bb105598a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 9,019; copy number 3: 2,562; copy number 4: 33,121; copy number 5: 7,538; copy number 6: 5,032; copy number 7: 1,322; copy number 8: 64; copy number 9: 1,012; copy number 10: 130; copy number 12: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A5GS-06A-11D-A27J-01): tumor purity 0.79, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,994,618–88,584,530, 4 genes (within-gene range 0–2): AC063965.1, MED6P1, AL353149.1, RNLS.
- chr21:26,917,922–27,143,949, 3 genes (within-gene range 0–2): ADAMTS5, MIR4759, GPX1P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,154 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–27,844,564, 488 genes, copy number 9 (broad region; genes not listed).
- chr7:27,873,785–27,876,546, 1 gene, copy number 9: AC004549.1.
- chr8:97,775,057–97,853,013, 1 gene, copy number 9 (within-gene range 6–9): LAPTM4B.
- chr8:97,853,021–140,638,283, 559 genes, copy number 9–10 (broad region; genes not listed).
- chr9:30,388,935–34,520,988, 105 genes, copy number 9–12 (within-gene range 4–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
